Somatic mutation profile of tumor specimen ALCH-B1X1-TTP1-A (aliquot ALCH-B1X1-TTP1-A-1-0-D-A771-36) from ALCHEMIST case ALCH-B1X1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,288 days).
Specimen ALCH-B1X1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a396d77a-9574-4089-8144-815dcea45369.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1X1-NB1-A (Blood Derived Normal), aliquot ALCH-B1X1-NB1-A-1-0-D-A771-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a51fe129-0f7f-42e2-88f3-0d1eddbad39d

The open-access MAF lists 182 somatic variants for this specimen: 119 protein-altering or splice-affecting, 43 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 43, Intron 10, Nonsense Mutation 6, 3'UTR 5, Splice Site 3, RNA 3, Frame Shift Del 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT9 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 34/279 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519957, COSV55299607; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 65/296 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PDHA1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs794729213, CM000553, CM013279, COSV63328534; ClinVar: pathogenic; called by muse, mutect2
- ADGRE1 | c.1912C>T p.H638Y | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779598111; called by muse, mutect2
- ARHGAP11B | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs1484028194; called by muse, mutect2, varscan2
- ARHGAP15 | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.416); catalogued as COSV54499042; called by muse, mutect2
- CACNB2 | c.564G>C p.Q188H (on ENST00000324631 / NM_201596.3; = p.Q133H on NM_000724.4) | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs1162742745, COSV99996481; called by muse, mutect2
- CARD11 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as COSV62717219, COSV62720087; called by muse, mutect2
- CCR3 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62462270; called by muse, mutect2, varscan2
- CD44 | c.784A>C p.T262P | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs1409453395; called by muse, mutect2
- DEGS1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100083472; called by muse, mutect2
- DEPDC4 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 14/282 reads (5%) | catalogued as rs1475002329; called by muse, mutect2
- EEF1A1 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV58549515; called by muse, mutect2
- EEF1A1 | c.1294A>T p.T432S | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV58548569, COSV58549078; called by muse, mutect2
- GAS6 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV59850394; called by muse, mutect2
- GATAD2A | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1260870038; called by muse, mutect2, varscan2
- H3C3 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 31/376 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); catalogued as COSV63550632, COSV63551056; called by muse, mutect2
- HJV | c.1111C>A p.P371T (on ENST00000336751 / NM_213653.4; = p.P258T on NM_145277.5) | Missense Mutation (SNP) | VAF 87/789 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.6); catalogued as COSV60952592; called by muse, mutect2, varscan2
- HK3 | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 24/299 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99457908; called by muse, mutect2
- ITGA2B | c.2782C>A p.R928S | Missense Mutation (SNP) | VAF 54/361 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs763637665; called by muse, mutect2, varscan2
- MRPS23 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs112828414; called by muse, mutect2, varscan2
- MYH1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV56846510; called by muse, mutect2
- NOL4 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99305789; called by muse, mutect2
- OR10A4 | c.689C>A p.P230Q | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV65842261, COSV65842873; called by muse, mutect2
- OR10R2 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100936752; called by muse, mutect2, varscan2
- PKD1L1 | c.8524G>A p.E2842K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as rs1429348495, COSV51845466; called by mutect2, varscan2
- PLA2G6 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 36/526 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.719); catalogued as rs555601622; called by muse, mutect2
- PRELID1 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 56/608 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1034363605; called by muse, mutect2
- PRRX1 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 53/389 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99509776; called by muse, mutect2, varscan2
- PSKH2 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 48/698 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV52611541; called by muse, mutect2
- RSL1D1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs766501222, COSV63077384, COSV63077443; called by muse, mutect2
- RTCA | c.706A>G p.K236E | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs1358218960; called by muse, mutect2
- SPRR3 | c.500A>T p.K167M | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99768763; called by mutect2, varscan2
- SPTAN1 | c.3161G>A p.R1054H | Missense Mutation (SNP) | VAF 23/566 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs561564501, COSV63986436; ClinVar: uncertain significance; called by muse, mutect2
- SRM | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs1207302757; called by muse, mutect2
- TSNAXIP1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.298); catalogued as rs1483858060; called by muse, mutect2
- TTC37 | c.1960C>G p.Q654E | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62453385; called by muse, mutect2
- XIAP | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as CM064995; called by muse, mutect2
- ZNF700 | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.139); catalogued as COSV54314593; called by muse, mutect2
- ZNF875 | c.1046G>C p.R349P | Missense Mutation (SNP) | VAF 21/284 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60992534, COSV60993730; called by muse, mutect2
- ABCA9 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ABCB11 | c.3428A>G p.D1143G | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.338); called by muse, mutect2
- ADRA2B | c.410G>A p.W137* | Nonsense Mutation (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- ANKRD35 | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 19/140 reads (14%) | called by muse, mutect2, varscan2
- APCDD1L | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.015); called by muse, mutect2
- ARHGAP27 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 39/440 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2
- ASH1L | c.3682G>C p.E1228Q | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ASH1L | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ATP8B4 | c.749-2A>T p.X250_splice | Splice Site (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2, varscan2
- BOD1 | c.428A>G p.H143R | Missense Mutation (SNP) | VAF 25/472 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- CASP5 | c.51G>T p.M17I | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- CD5L | c.603C>G p.I201M | Missense Mutation (SNP) | VAF 17/557 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- CD99L2 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- CLMP | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 26/399 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); called by muse, mutect2
- COL16A1 | c.2539G>A p.G847S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- CRTC2 | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.089); called by muse, mutect2
- DEXI | c.58G>C p.V20L | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.009); called by muse, mutect2
- DLGAP2 | c.227C>G p.P76R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNHD1 | c.4943_4947del p.L1648Qfs*8 | Frame Shift Del (DEL) | VAF 26/249 reads (10%) | called by mutect2, pindel, varscan2
- DUS1L | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.58); called by muse, mutect2
- EXOC2 | c.2381-2A>T p.X794_splice | Splice Site (SNP) | VAF 11/214 reads (5%) | called by muse, mutect2
- EXPH5 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
- FLG | c.9370T>A p.Y3124N | Missense Mutation (SNP) | VAF 68/402 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXD3 | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.081); called by muse, mutect2
- GNPDA2 | c.117A>T p.L39F | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRXCR1 | c.89A>T p.K30M | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2
- GTF2IRD1 | c.28G>T p.V10F | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.118); called by muse, mutect2
- HEATR5A | c.2093G>C p.R698T | Missense Mutation (SNP) | VAF 25/374 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2
- HECTD3 | c.119T>A p.L40Q | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HIPK1 | c.2104-2A>T p.X702_splice | Splice Site (SNP) | VAF 13/158 reads (8%) | called by muse, mutect2
- IGFBP7 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KDM2A | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- LAMA4 | c.2669C>A p.A890D (on ENST00000230538 / NM_001105206.3; = p.A883D on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- LIN9 | c.845A>G p.D282G (on ENST00000366808 / NM_001270410.2; = p.D227G on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); called by muse, mutect2
- LRRC30 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- MAGI2 | c.83T>A p.L28Q | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- MEFV | c.1178C>A p.P393H | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- MMP16 | c.267C>A p.D89E | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- MUC16 | c.32551C>A p.P10851T | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MUC16 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); called by muse, mutect2
- MUC17 | c.8543G>T p.S2848I | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- MUC5AC | c.1581C>G p.I527M | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- MYH11 | c.2761G>C p.E921Q | Missense Mutation (SNP) | VAF 20/586 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- MYH8 | c.2786C>A p.A929D | Missense Mutation (SNP) | VAF 50/685 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2
- NEK4 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); called by muse, mutect2
- ONECUT3 | c.1145G>T p.W382L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10R2 | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR2AK2 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- OR4A47 | c.806T>G p.V269G | Missense Mutation (SNP) | VAF 20/375 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- OR5B21 | c.392C>A p.T131N | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); called by muse, mutect2
- OR5M8 | c.461C>G p.T154S | Missense Mutation (SNP) | VAF 20/419 reads (5%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.665); called by muse, mutect2
- PAK5 | c.1384A>T p.I462F | Missense Mutation (SNP) | VAF 40/431 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2
- PCDHB10 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 34/414 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- PCDHGB3 | c.248A>T p.N83I | Missense Mutation (SNP) | VAF 23/351 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2
- PCF11 | c.3433G>T p.A1145S | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- PEG3 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2
- PGAM1 | c.757A>C p.K253Q | Missense Mutation (SNP) | VAF 10/343 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2
- PLXNA4 | c.4787C>T p.A1596V | Missense Mutation (SNP) | VAF 36/445 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPARGC1B | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- PPARGC1B | c.35A>T p.E12V | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2
- PTPRH | c.2308G>T p.G770C | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2
- RSPRY1 | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- SERPINB2 | c.1174C>A p.H392N | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- SLAMF1 | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 35/451 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SMO | c.1386T>A p.F462L | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPRED3 | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 24/385 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TLR4 | c.1451A>G p.Q484R (on ENST00000355622 / NM_138554.5; = p.Q444R on NM_003266.4) | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- TNXB | c.5750G>T p.S1917I (on ENST00000647633; = p.S1670I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); called by muse, mutect2
- TP53 | c.241A>T p.T81S | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.014); called by muse, mutect2
- TRIM51 | c.1042G>T p.G348W | Missense Mutation (SNP) | VAF 40/504 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TSC2 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 56/560 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2
- USH2A | c.2390G>C p.C797S | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VWF | c.3841C>A p.L1281M | Missense Mutation (SNP) | VAF 133/582 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZAR1L | c.86A>T p.H29L | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ZDBF2 | c.4789T>A p.C1597S | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZDHHC11 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- ZNF154 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- ZNF583 | c.1265A>T p.Y422F | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZNF761 | c.1973G>T p.G658V | Missense Mutation (SNP) | VAF 25/456 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- ABI3BP | c.714G>A p.R238= | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as COSV99427912; called by muse, mutect2
- ACSM5 | c.1062G>A p.V354= | Silent (SNP) | VAF 22/629 reads (3%) | called by muse, mutect2
- ADAMTS12 | c.207T>C p.Y69= | Silent (SNP) | VAF 40/391 reads (10%) | catalogued as rs776284384; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1071C>T p.P357= | Silent (SNP) | VAF 32/264 reads (12%) | called by muse, mutect2, varscan2
- ANKRD26 | c.162C>T p.A54= | Silent (SNP) | VAF 36/636 reads (6%) | catalogued as rs761866364; ClinVar: benign; called by muse, mutect2
- AXL | c.2466C>G p.V822= (on ENST00000301178 / NM_021913.5; = p.V813= on NM_001699.6) | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as COSV56576153; called by muse, mutect2
- B4GALT1 | c.1074A>T p.R358= | Silent (SNP) | VAF 14/509 reads (3%) | called by muse, mutect2
- CLU | c.315C>T p.T105= | Silent (SNP) | VAF 28/477 reads (6%) | catalogued as rs746782662; called by muse, mutect2
- COL3A1 | c.1632A>T p.G544= | Silent (SNP) | VAF 25/387 reads (6%) | catalogued as COSV100483382; called by muse, mutect2
- CRTC2 | c.957C>T p.I319= | Silent (SNP) | VAF 7/161 reads (4%) | called by muse, mutect2
- CSF1R | c.1104G>T p.L368= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- CUBN | c.9616C>T p.L3206= | Silent (SNP) | VAF 12/279 reads (4%) | catalogued as COSV100913664; called by muse, mutect2
- CYP3A4 | c.531G>A p.G177= | Silent (SNP) | VAF 69/464 reads (15%) | catalogued as rs1160121786; called by muse, mutect2, varscan2
- FAM83H | c.2328A>G p.P776= | Silent (SNP) | VAF 13/325 reads (4%) | called by muse, mutect2
- FCN1 | c.18C>T p.A6= | Silent (SNP) | VAF 21/234 reads (9%) | catalogued as rs1179461436; called by muse, mutect2
- HOXD1 | c.660C>A p.L220= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- HSPA2 | c.162C>T p.D54= | Silent (SNP) | VAF 59/416 reads (14%) | catalogued as COSV55969815; called by muse, mutect2, varscan2
- INTS5 | c.1614A>G p.L538= | Silent (SNP) | VAF 30/295 reads (10%) | called by muse, mutect2, varscan2
- KIAA1671 | c.4968G>T p.R1656= | Silent (SNP) | VAF 24/308 reads (8%) | called by muse, mutect2
- KIF21A | c.4008A>T p.P1336= (on ENST00000361418 / NM_001378440.1; = p.P1323= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/265 reads (14%) | catalogued as rs779657868; called by muse, mutect2, varscan2
- LRTM2 | c.264C>T p.F88= | Silent (SNP) | VAF 36/253 reads (14%) | catalogued as rs368418051; called by muse, mutect2, varscan2
- MKRN2OS | c.474G>A p.T158= | Silent (SNP) | VAF 25/437 reads (6%) | catalogued as rs759356593; called by muse, mutect2
- MON2 | c.2232A>T p.P744= | Silent (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- MSX2 | c.525C>T p.F175= | Silent (SNP) | VAF 34/574 reads (6%) | called by muse, mutect2
- MUC7 | c.300G>T p.V100= | Silent (SNP) | VAF 29/275 reads (11%) | called by muse, mutect2, varscan2
- PCDH15 | c.5025T>C p.P1675= (on ENST00000644397 / NM_001354429.2; = p.P1617= on NM_001142771.2) | Silent (SNP) | VAF 58/813 reads (7%) | catalogued as COSV64698605; called by muse, mutect2
- PCDHB9 | c.2316C>T p.P772= | Silent (SNP) | VAF 25/241 reads (10%) | called by muse, mutect2, varscan2
- POM121L12 | c.585G>T p.P195= | Silent (SNP) | VAF 34/306 reads (11%) | catalogued as COSV68692555; called by muse, mutect2, varscan2
- POM121L2 | c.642G>C p.P214= | Silent (SNP) | VAF 32/355 reads (9%) | called by muse, mutect2
- PRR36 | c.3804G>C p.A1268= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- PRRC2C | c.6930A>T p.S2310= (on ENST00000367742; = p.S2308= on NM_015172.4) | Silent (SNP) | VAF 24/355 reads (7%) | called by muse, mutect2
- RNPEP | c.690G>C p.L230= | Silent (SNP) | VAF 11/328 reads (3%) | called by muse, mutect2
- RYR2 | c.10944G>T p.G3648= | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- SETBP1 | c.2485C>T p.L829= | Silent (SNP) | VAF 28/620 reads (5%) | catalogued as rs867619925; called by muse, mutect2
- SIPA1L3 | c.2727C>T p.F909= | Silent (SNP) | VAF 10/231 reads (4%) | catalogued as COSV55908112; called by muse, mutect2
- SLCO5A1 | c.1809T>C p.C603= | Silent (SNP) | VAF 19/197 reads (10%) | called by muse, mutect2
- SMAD6 | c.1113C>G p.L371= | Silent (SNP) | VAF 14/397 reads (4%) | catalogued as rs1342763563; called by muse, mutect2
- TAF1 | c.4263T>G p.S1421= (on ENST00000373790 / NM_138923.4; = p.S1442= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/117 reads (20%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.1293T>A p.G431= | Silent (SNP) | VAF 7/137 reads (5%) | catalogued as COSV99516357; called by muse, mutect2
- TNFRSF11B | c.1041C>T p.H347= | Silent (SNP) | VAF 26/263 reads (10%) | catalogued as rs766402871, COSV52074160; called by muse, mutect2, varscan2
- ZNF75A | c.660A>T p.S220= | Silent (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- ZNF99 | c.1401C>A p.A467= | Silent (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- ZSCAN10 | c.222G>T p.A74= (on ENST00000252463; = p.A129= on NM_032805.3) | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- ATP11C | c.3298-704C>G | Intron (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- CCDC91 | c.-12G>T | 5'UTR (SNP) | VAF 27/218 reads (12%) | called by muse, mutect2, varscan2
- F13A1 | c.319+59G>A | Intron (SNP) | VAF 34/367 reads (9%) | called by muse, mutect2
- FGFR1 | c.937-1230C>T | Intron (SNP) | VAF 34/358 reads (9%) | catalogued as rs747250463; called by muse, mutect2
- GK | c.*37T>C | 3'UTR (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- GPATCH8 | c.*2084G>C | 3'UTR (SNP) | VAF 10/288 reads (3%) | called by muse, mutect2
- GYPA | c.232+22G>T | Intron (SNP) | VAF 20/272 reads (7%) | catalogued as rs1467298873; called by muse, mutect2
- HMGN2P46 | n.855C>A | RNA (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- HTR3E | c.68-78G>T | Intron (SNP) | VAF 18/154 reads (12%) | catalogued as COSV58947130; called by muse, mutect2
- MED21 | c.*1745C>G | 3'UTR (SNP) | VAF 36/246 reads (15%) | catalogued as rs1330327792; called by muse, mutect2, varscan2
- MIR508 | n.42A>G | RNA (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- PRB3 | c.*89T>A | 3'UTR (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- PRDM11 | c.657-6113G>T | Intron (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- PRDM11 | c.657-6112G>T | Intron (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- RECK | c.405+1214C>T | Intron (SNP) | VAF 10/223 reads (4%) | called by muse, mutect2
- TNIP3 | c.*10C>T | 3'UTR (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
- TPSD1 | chr16:1262477 C>A | 3'Flank (SNP) | VAF 31/310 reads (10%) | called by muse, mutect2, varscan2
- UBAP2L | c.2902+1442C>T | Intron (SNP) | VAF 42/398 reads (11%) | catalogued as rs932470272; called by muse, mutect2
- ZEB1 | c.58+43818G>T | Intron (SNP) | VAF 40/578 reads (7%) | called by muse, mutect2
- ZNF252P | n.1367A>G | RNA (SNP) | VAF 13/85 reads (15%) | catalogued as rs775395495; called by muse, mutect2, varscan2
